HCMI case HCM-BROD-0791-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/575844b7-cfa1-406a-b0dd-d55cf9fff978

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Dead; Days to death: 2,161 days (5.9 years); Cause of death: Cancer Related.

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,298 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T1b; AJCC pathologic N: N2; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IIIC; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 196 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Ipilimumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,999 days (5.5 years); Days to treatment end: 2,062 days (5.6 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C79.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 66.7 years (24,346 days); Days to diagnosis: 2,048 days (5.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: BRAFV600/PI3K Inhibitor ASN003 + Binimetinib + Entinostat + Ipilimumab + Nivolumab + PI3K-gamma Inhibitor IPI-549 + Pembrolizumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 33 days; Days to treatment end: 2,038 days (5.6 years); Treatment outcome: Progressive Disease.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C79.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 66.8 years (24,405 days); Days to diagnosis: 2,107 days (5.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: BRAFV600/PI3K Inhibitor ASN003 + Binimetinib + Entinostat + Ipilimumab + Nivolumab + PI3K-gamma Inhibitor IPI-549 + Pembrolizumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 33 days; Days to treatment end: 2,089 days (5.7 years); Treatment outcome: Progressive Disease.

Follow-up (2 entries)
- Days to follow up: 2,161 days (5.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 2,155.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- NRAS mutation, nos: Positive; Amino-acid change: Q61K.
- TP53 mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 176 cm; BMI: 19.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0791-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide HCM-BROD-0791-C43-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 21; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 8.
  Slide HCM-BROD-0791-C43-06A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 8.
- Sample HCM-BROD-0791-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0791-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
- Sample HCM-BROD-0791-C43-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 22.
